Somatic mutation profile of cancer-model specimen HCM-CSHL-0867-C18-85B (3D Organoid, passage 4; aliquot HCM-CSHL-0867-C18-85B-01D-A88H-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0867-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Appendix; AJCC pathologic stage: Stage IVC; Tumor grade: G2; Age at diagnosis: 68.4 years (24,985 days).
Specimen HCM-CSHL-0867-C18-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7c08f20-ec87-408e-b63d-d7f560e9b91b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0867-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0867-C18-10A-01D-A88H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/570e1d6f-ef47-4dca-b934-60e9046484e1

The open-access MAF lists 346 somatic variants for this specimen: 258 protein-altering or splice-affecting, 79 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 236, Silent 79, Frame Shift Del 8, Nonsense Mutation 7, Intron 4, Splice Site 3, Frame Shift Ins 3, 5'UTR 2, 3'UTR 2, 3'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 209/429 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913413, COSV62688008, COSV62688560, COSV62714333; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 118/282 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 291/292 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- SMAD4 | c.1245_1248del p.D415Efs*20 | Frame Shift Del (DEL) | VAF 151/157 reads (96%) | catalogued as rs80338965; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SYN1 | c.1648G>A p.A550T | Missense Mutation (SNP) | VAF 379/799 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as rs397514680, CM113535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.2863C>T p.P955S (on ENST00000614293; = p.P925S on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 207/408 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99688514; called by muse, mutect2, varscan2
- ABCF2 | c.1373C>G p.S458C | Missense Mutation (SNP) | VAF 146/304 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs143636020; called by muse, mutect2, varscan2
- ADCY2 | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 156/352 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs1410091098, COSV57859838; called by muse, mutect2, varscan2
- ADGRG4 | c.8936G>T p.G2979V | Missense Mutation (SNP) | VAF 140/326 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54963928; called by muse, mutect2, varscan2
- AK1 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 199/484 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs146320071; called by muse, mutect2, varscan2
- ALDH1B1 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 217/450 reads (48%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs138929946; called by muse, mutect2, varscan2
- ALPI | c.661G>A p.G221R | Missense Mutation (SNP) | VAF 105/247 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1231327501; called by muse, mutect2, varscan2
- APOB | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 192/389 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as rs145661815; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP39 | c.2659A>G p.M887V (on ENST00000276826 / NM_001308208.2; = p.M918V on NM_025251.2) | Missense Mutation (SNP) | VAF 326/983 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs1172257578, COSV52769642; called by muse, mutect2, varscan2
- ARID3C | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 297/604 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as rs773355028, COSV99427190; called by muse, mutect2, varscan2
- ATAD3A | c.1183A>C p.N395H | Missense Mutation (SNP) | VAF 235/453 reads (52%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as rs142781267; called by muse, mutect2, varscan2
- ATP8B3 | c.1201G>A p.G401S | Missense Mutation (SNP) | VAF 176/347 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.058); catalogued as rs745619434, COSV59542722; called by muse, mutect2, varscan2
- ATXN1L | c.1679C>T p.T560M | Missense Mutation (SNP) | VAF 205/459 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1405847666, COSV70235623; called by muse, mutect2, varscan2
- AVPR1A | c.1071A>C p.Q357H | Missense Mutation (SNP) | VAF 45/457 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.042); catalogued as rs746853343; called by muse, mutect2, varscan2
- BAG2 | c.328C>G p.L110V | Missense Mutation (SNP) | VAF 211/441 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58099634; called by muse, mutect2, varscan2
- BARHL2 | c.172G>A p.V58I | Missense Mutation (SNP) | VAF 275/574 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.959); catalogued as rs150916366, COSV64980840; called by muse, mutect2, varscan2
- BMP5 | c.847G>A p.V283I | Missense Mutation (SNP) | VAF 147/277 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs748147968; called by muse, mutect2, varscan2
- BTBD10 | c.1237C>T p.R413W | Missense Mutation (SNP) | VAF 180/437 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1313324379; called by muse, mutect2, varscan2
- CAVIN2 | c.787G>A p.V263I | Missense Mutation (SNP) | VAF 201/447 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV99079550; called by muse, mutect2, varscan2
- CBFA2T2 | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 186/409 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs1304951120; called by muse, mutect2, varscan2
- CBLN2 | c.225C>A p.D75E | Missense Mutation (SNP) | VAF 251/479 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0.062); catalogued as rs1376214305, COSV54052958; called by muse, mutect2, varscan2
- CBY2 | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 305/563 reads (54%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.035); catalogued as rs1453986677, COSV60117059; called by muse, mutect2, varscan2
- CCDC121 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 202/431 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV53112323; called by muse, mutect2, varscan2
- CCDC88B | c.2953C>T p.R985C | Missense Mutation (SNP) | VAF 199/423 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs957872352; called by muse, mutect2, varscan2
- CDC20B | c.1205C>T p.T402M | Missense Mutation (SNP) | VAF 119/264 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs138334108; called by muse, mutect2, varscan2
- CEP76 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 180/390 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.056); catalogued as rs762993284; called by muse, mutect2, varscan2
- CGB8 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 104/829 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1449050206; called by muse, mutect2, varscan2
- CHD5 | c.4237G>A p.A1413T | Missense Mutation (SNP) | VAF 259/541 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99313798; called by muse, mutect2, varscan2
- CHRNA1 | c.1246G>A p.E416K (on ENST00000261007 / NM_001039523.3; = p.E391K on NM_000079.4) | Missense Mutation (SNP) | VAF 222/483 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.641); catalogued as rs762411124, COSV53682209; called by muse, mutect2, varscan2
- CLEC4F | c.1194G>T p.K398N | Missense Mutation (SNP) | VAF 188/356 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); catalogued as rs782605931; called by muse, mutect2, varscan2
- CNTN6 | c.235T>G p.L79V | Missense Mutation (SNP) | VAF 152/401 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.745); catalogued as COSV63165848; called by muse, mutect2, varscan2
- COL15A1 | c.3034C>T p.P1012S | Missense Mutation (SNP) | VAF 116/245 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100897573; called by muse, mutect2, varscan2
- CPVL | c.512A>C p.N171T | Missense Mutation (SNP) | VAF 118/279 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.152); catalogued as rs775653828; called by muse, mutect2, varscan2
- CTNND1 | c.2389C>T p.R797* (on ENST00000399050 / NM_001085458.2; = p.R791* on NM_001331.3) | Nonsense Mutation (SNP) | VAF 184/382 reads (48%) | catalogued as COSV62387156; called by muse, mutect2, varscan2
- CTNND2 | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 142/323 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs747652289, COSV58912091; called by muse, mutect2, varscan2
- DHDH | c.574C>A p.Q192K | Missense Mutation (SNP) | VAF 180/813 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV55482908; called by muse, mutect2, varscan2
- DOCK5 | c.4957C>T p.R1653C | Missense Mutation (SNP) | VAF 139/524 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as rs777838021; called by muse, mutect2, varscan2
- ERMARD | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 203/405 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs1405133707, COSV64647558; called by muse, mutect2, varscan2
- FAM3A | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 180/461 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1324453425, COSV59194230; called by muse, mutect2, varscan2
- FHOD3 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 88/496 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754354392, COSV57167694; called by muse, mutect2, varscan2
- FOXS1 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 296/657 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770771838, COSV99639703; called by muse, mutect2, varscan2
- GOLGA6A | c.1634C>T p.T545M | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as rs1289445564, COSV99297097; called by mutect2, varscan2
- GPSM1 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 205/416 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.327); catalogued as rs782092540; called by muse, mutect2, varscan2
- GRM4 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 290/564 reads (51%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.832); catalogued as rs368604495; called by muse, mutect2, varscan2
- HMCN2 | c.13843G>A p.E4615K | Missense Mutation (SNP) | VAF 231/486 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.14); catalogued as rs755110693; called by muse, mutect2, varscan2
- HNMT | c.638T>G p.L213R | Missense Mutation (SNP) | VAF 48/469 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs748842042; called by muse, mutect2
- HTR1B | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 235/520 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV64051212, COSV64051303; called by muse, mutect2, varscan2
- HYKK | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 186/397 reads (47%) | SIFT tolerated (0.55); PolyPhen benign (0.031); catalogued as rs771215176; called by muse, mutect2, varscan2
- IGHA1 | c.446T>C p.L149P | Missense Mutation (SNP) | VAF 286/567 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758157934; called by muse, mutect2, varscan2
- IGSF1 | c.1822T>A p.L608I | Missense Mutation (SNP) | VAF 326/638 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.201); catalogued as COSV104421380; called by mutect2, varscan2
- ITCH | c.2506C>T p.R836* (on ENST00000262650 / NM_001257137.3; = p.R795* on NM_031483.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 110/254 reads (43%) | catalogued as rs368005062; called by muse, mutect2, varscan2
- ITGB5 | c.617A>G p.K206R | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); catalogued as COSV56146593; called by muse, mutect2
- ITPR2 | c.6989G>A p.R2330H | Missense Mutation (SNP) | VAF 142/282 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.955); catalogued as rs201868488, COSV101189898; called by muse, mutect2, varscan2
- KLHL4 | c.1084G>A p.G362R | Missense Mutation (SNP) | VAF 251/524 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV64139420; called by muse, mutect2, varscan2
- LIMCH1 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 191/433 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV58297646; called by muse, mutect2, varscan2
- LRRC38 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 263/566 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1395738394; called by muse, mutect2, varscan2
- MAGEA10 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 158/382 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.07); catalogued as rs145553450, COSV54884254; called by muse, mutect2, varscan2
- MAGEC1 | c.1527del p.Q511Sfs*119 | Frame Shift Del (DEL) | VAF 226/628 reads (36%) | catalogued as COSV53567467; called by pindel, varscan2
- MALRD1 | c.3749C>T p.S1250F | Missense Mutation (SNP) | VAF 148/303 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV66005773; called by muse, mutect2, varscan2
- MAP1B | c.6475G>A p.D2159N | Missense Mutation (SNP) | VAF 249/494 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57102978, COSV57104636; called by muse, mutect2, varscan2
- MAP2 | c.4723C>T p.R1575W | Missense Mutation (SNP) | VAF 147/237 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757232375; called by muse, mutect2, varscan2
- MDGA2 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 236/543 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.711); catalogued as rs1016997159; called by muse, mutect2, varscan2
- MET | c.2873G>A p.R958K | Missense Mutation (SNP) | VAF 111/233 reads (48%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV59268688; called by muse, mutect2, varscan2
- MPPED1 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 217/468 reads (46%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.851); catalogued as rs1337130005; called by muse, mutect2, varscan2
- MTERF1 | c.443A>C p.K148T | Missense Mutation (SNP) | VAF 217/437 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV61098833; called by muse, mutect2, varscan2
- MYT1L | c.3104C>T p.A1035V | Missense Mutation (SNP) | VAF 200/411 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.234); catalogued as COSV67702286; called by muse, varscan2
- NDUFS7 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 354/744 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs760431596, COSV52038755; called by muse, mutect2, varscan2
- NEXMIF | c.1796C>T p.T599M | Missense Mutation (SNP) | VAF 255/540 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.151); catalogued as rs1052758203; called by muse, mutect2, varscan2
- NPIPB15 | c.614dup p.S206Ffs*32 | Frame Shift Ins (INS) | VAF 284/1154 reads (25%) | catalogued as rs746174676; called by mutect2, varscan2
- OR4C15 | c.493G>T p.V165L (on ENST00000314644; = p.V111L on NM_001001920.2) | Missense Mutation (SNP) | VAF 233/499 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.065); catalogued as rs765799035, COSV58951882; called by muse, mutect2, varscan2
- OR8H3 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 125/329 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0.042); catalogued as rs893615303, COSV57908256, COSV57910768; called by muse, mutect2, varscan2
- ORC1 | c.2182C>T p.R728C | Missense Mutation (SNP) | VAF 224/457 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs143923779; called by muse, mutect2, varscan2
- PCDH17 | c.3043G>A p.V1015I | Missense Mutation (SNP) | VAF 282/483 reads (58%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.959); catalogued as rs770993611; called by muse, mutect2, varscan2
- PCDHGA3 | c.401C>G p.P134R | Missense Mutation (SNP) | VAF 124/295 reads (42%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV53933349; called by muse, mutect2
- PHF3 | c.4667C>T p.T1556M | Missense Mutation (SNP) | VAF 190/376 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.306); catalogued as rs767226434; called by muse, varscan2
- PLIN1 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 267/573 reads (47%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.589); catalogued as rs147302182; called by muse, mutect2, varscan2
- PMS2 | c.1841A>G p.K614R | Missense Mutation (SNP) | VAF 127/266 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as rs771892867; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POTEA | c.937C>A p.P313T (on ENST00000519951 / NM_001005365.2; = p.P267T on NM_001002920.1) | Missense Mutation (SNP) | VAF 239/362 reads (66%) | SIFT tolerated (0.21); PolyPhen benign (0.113); catalogued as rs367956975; called by muse, mutect2, varscan2
- PROSER2 | c.1130C>T p.T377M | Missense Mutation (SNP) | VAF 407/749 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as rs770720122; called by muse, mutect2, varscan2
- PRSS36 | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 216/447 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1460552045, COSV51639646; called by muse, mutect2, varscan2
- PTGER3 | c.1078G>A p.E360K (on ENST00000628037 / NM_198717.2; = p.E369K on NM_198716.2) | Missense Mutation (SNP) | VAF 128/245 reads (52%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.037); catalogued as COSV63392167; called by muse, mutect2, varscan2
- PTPN5 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 173/396 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as rs376076320, COSV100659775; called by muse, varscan2
- PTPRM | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 120/255 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs1237614240; called by muse, mutect2, varscan2
- RIT2 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 125/263 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs1162004248, COSV56301378; called by muse, mutect2, varscan2
- RNASE3 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 236/501 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.094); catalogued as rs760744021; called by muse, mutect2, varscan2
- RTL1 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 229/441 reads (52%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0); catalogued as rs745760683, COSV66017178; called by muse, mutect2, varscan2
- SCN11A | c.2395A>G p.K799E | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as rs914965285; called by muse, mutect2
- SCN5A | c.2712G>A p.W904* | Nonsense Mutation (SNP) | VAF 160/332 reads (48%) | catalogued as rs1553700581, COSV100346981; called by muse, mutect2, varscan2
- SEC61A2 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 173/326 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV53652179; called by muse, mutect2, varscan2
- SLAIN1 | c.1358C>T p.P453L (on ENST00000466548; = p.P190L on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 127/292 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144133289; called by muse, mutect2, varscan2
- SLC12A1 | c.66A>C p.Q22H | Missense Mutation (SNP) | VAF 20/356 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as COSV100372462; called by muse, mutect2
- SLC17A1 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 115/268 reads (43%) | SIFT tolerated (0.86); PolyPhen benign (0.015); catalogued as COSV99765875; called by muse, mutect2, varscan2
- SLC26A3 | c.2124A>G p.I708M | Missense Mutation (SNP) | VAF 146/318 reads (46%) | SIFT tolerated (0.77); PolyPhen benign (0.091); catalogued as rs1200350975; called by muse, mutect2, varscan2
- SLF2 | c.3401T>G p.L1134R | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs780661091, COSV53271700; called by muse, mutect2
- SPIN3 | c.47C>T p.T16M | Missense Mutation (SNP) | VAF 254/516 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as COSV66529331; called by muse, varscan2
- SPTAN1 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 161/335 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.909); catalogued as rs1325381089; called by muse, mutect2, varscan2
- SPTLC3 | c.1540G>A p.D514N | Missense Mutation (SNP) | VAF 114/243 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as rs538913638, COSV65463441; called by muse, mutect2, varscan2
- STAT4 | c.1813G>A p.G605R | Missense Mutation (SNP) | VAF 229/494 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771192197; called by muse, mutect2, varscan2
- TAS2R5 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 202/375 reads (54%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as rs142235954, COSV56095178; called by muse, mutect2, varscan2
- THG1L | c.517C>T p.L173F | Missense Mutation (SNP) | VAF 110/236 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.603); catalogued as rs1294302950; called by muse, mutect2, varscan2
- TMEM151A | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 80/555 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1457005077; called by muse, mutect2, varscan2
- TNXB | c.4901C>T p.S1634L (on ENST00000647633; = p.S1387L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 166/376 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64476044; called by muse, mutect2, varscan2
- UNC45B | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 167/331 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as rs200725658, COSV52096769; called by muse, mutect2, varscan2
- UNC79 | c.3883G>A p.A1295T (on ENST00000393151 / NM_001346218.2; = p.A1118T on NM_020818.5) | Missense Mutation (SNP) | VAF 247/514 reads (48%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.946); catalogued as rs1047896978, COSV56380985; called by muse, mutect2, varscan2
- USH2A | c.6049+1G>T p.X2017_splice | Splice Site (SNP) | VAF 46/573 reads (8%) | catalogued as CS155003; called by muse, mutect2
- WFIKKN2 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 246/478 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs765589347, COSV60957947; called by muse, mutect2, varscan2
- XPO7 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 187/621 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1156913632, COSV53016713; called by muse, mutect2, varscan2
- ZAN | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 248/516 reads (48%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.766); catalogued as rs752389582; called by muse, mutect2, varscan2
- ZFYVE9 | c.2804G>A p.G935D | Missense Mutation (SNP) | VAF 167/365 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as COSV55092658; called by muse, mutect2, varscan2
- ZNF35 | c.451G>C p.E151Q | Missense Mutation (SNP) | VAF 16/364 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV56075939; called by muse, mutect2
- ZNF43 | c.1418A>C p.K473T | Missense Mutation (SNP) | VAF 141/262 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV61682889; called by muse, mutect2, varscan2
- ZNF492 | c.182dup p.N61Kfs*12 | Frame Shift Ins (INS) | VAF 78/164 reads (48%) | catalogued as rs754633801; called by mutect2, varscan2
- ZNF678 | c.325A>G p.R109G (on ENST00000343776 / NM_001367910.1; = p.R164G on NM_178549.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 115/583 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV59384909; called by muse, mutect2, varscan2
- ZNF681 | c.1670C>A p.T557N | Missense Mutation (SNP) | VAF 164/307 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs749950289; called by muse, mutect2, varscan2
- ZNF692 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 784/1046 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs764536582; called by muse, mutect2, varscan2
- ZNF786 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 278/552 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs773179415, COSV60277607; called by muse, mutect2, varscan2
- ZNRF4 | c.1048G>A p.V350M | Missense Mutation (SNP) | VAF 282/614 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.196); catalogued as rs540854812, COSV55773698; called by muse, mutect2, varscan2
- ABCC12 | c.86T>C p.L29P | Missense Mutation (SNP) | VAF 34/424 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- ABR | c.874G>A p.V292M (on ENST00000302538 / NM_021962.5; = p.V255M on NM_001092.5) | Missense Mutation (SNP) | VAF 244/540 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ACACB | c.106A>G p.K36E | Missense Mutation (SNP) | VAF 197/430 reads (46%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRB1 | c.2438C>T p.S813F | Missense Mutation (SNP) | VAF 450/450 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKAP5 | c.150A>C p.K50N | Missense Mutation (SNP) | VAF 22/407 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); called by muse, mutect2
- ALMS1 | c.7358del p.K2453Rfs*4 | Frame Shift Del (DEL) | VAF 145/352 reads (41%) | called by mutect2, pindel, varscan2
- ANK1 | c.383A>C p.K128T | Missense Mutation (SNP) | VAF 177/574 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ANKRD11 | c.1820A>G p.K607R | Missense Mutation (SNP) | VAF 47/596 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.056); called by muse, mutect2
- APOBEC4 | c.607A>C p.S203R | Missense Mutation (SNP) | VAF 61/1167 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.181); called by muse, mutect2
- APOM | c.53A>C p.N18T | Missense Mutation (SNP) | VAF 32/570 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); called by muse, mutect2
- ATG7 | c.598T>G p.L200V | Missense Mutation (SNP) | VAF 176/424 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ATP10A | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 133/229 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- B2M | c.124T>A p.F42I | Missense Mutation (SNP) | VAF 238/506 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- B3GALT4 | c.277_290del p.S93Afs*30 | Frame Shift Del (DEL) | VAF 370/859 reads (43%) | called by mutect2, pindel, varscan2
- B3GAT1 | c.584A>C p.D195A | Missense Mutation (SNP) | VAF 205/434 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- B4GALT7 | c.713_723+14del p.X238_splice | Splice Site (DEL) | VAF 86/269 reads (32%) | called by mutect2, pindel, varscan2
- BCLAF1 | c.1349G>A p.S450N | Missense Mutation (SNP) | VAF 114/399 reads (29%) | SIFT tolerated (0.96); PolyPhen benign (0.026); called by muse, mutect2
- BMX | c.265C>A p.L89I | Missense Mutation (SNP) | VAF 12/356 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- BRCA1 | c.4063A>T p.N1355Y | Missense Mutation (SNP) | VAF 264/569 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- BRSK1 | c.497A>T p.E166V | Missense Mutation (SNP) | VAF 24/604 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- C4orf47 | c.605A>G p.Y202C | Missense Mutation (SNP) | VAF 107/250 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- CARMIL3 | c.1937A>C p.E646A | Missense Mutation (SNP) | VAF 70/515 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- CASS4 | c.2195A>G p.E732G | Missense Mutation (SNP) | VAF 32/585 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- CBARP | c.292+1G>A p.X98_splice (on ENST00000382477; = p.X104_splice on NM_152769.3) | Splice Site (SNP) | VAF 266/543 reads (49%) | called by muse, mutect2, varscan2
- CCDC110 | c.1454A>C p.E485A | Missense Mutation (SNP) | VAF 90/200 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- CCDC168 | c.10986G>T p.K3662N | Missense Mutation (SNP) | VAF 168/359 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CD55 | c.275A>G p.E92G | Missense Mutation (SNP) | VAF 22/365 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- CENPVL3 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 341/784 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- CGN | c.3272A>T p.D1091V | Missense Mutation (SNP) | VAF 119/536 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHD6 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 197/346 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- CLK2 | c.311A>T p.E104V | Missense Mutation (SNP) | VAF 67/1619 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.059); called by muse, mutect2
- CNTN4 | c.1936A>G p.S646G | Missense Mutation (SNP) | VAF 145/258 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DDX28 | c.1379G>A p.G460D | Missense Mutation (SNP) | VAF 203/406 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDX56 | c.600del p.F200Lfs*11 | Frame Shift Del (DEL) | VAF 96/245 reads (39%) | called by mutect2, pindel, varscan2
- DIXDC1 | c.695A>G p.E232G (on ENST00000440460 / NM_001037954.4; = p.E21G on NM_033425.4) | Missense Mutation (SNP) | VAF 26/426 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- DNAJC28 | c.620T>G p.L207R | Missense Mutation (SNP) | VAF 46/566 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNASE1L1 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 225/469 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- DOCK11 | c.2918C>T p.A973V | Missense Mutation (SNP) | VAF 60/200 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYRK3 | c.1711T>A p.S571T | Missense Mutation (SNP) | VAF 186/722 reads (26%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EFTUD2 | c.731A>C p.K244T | Missense Mutation (SNP) | VAF 44/474 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- EIF2B4 | c.629T>G p.L210R (on ENST00000347454 / NM_001034116.2; = p.L209R on NM_015636.3) | Missense Mutation (SNP) | VAF 35/343 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EPHA8 | c.39G>C p.W13C | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- EPX | c.1241T>A p.L414Q | Missense Mutation (SNP) | VAF 198/393 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EZHIP | c.313A>C p.S105R | Missense Mutation (SNP) | VAF 195/497 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- EZHIP | c.1228T>C p.S410P | Missense Mutation (SNP) | VAF 22/588 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FBXO40 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 219/483 reads (45%) | called by muse, mutect2, varscan2
- FCHSD2 | c.1034A>G p.Q345R | Missense Mutation (SNP) | VAF 88/212 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- FPR3 | c.596A>C p.K199T | Missense Mutation (SNP) | VAF 36/986 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- FZD10 | c.1696dup p.T566Nfs*7 | Frame Shift Ins (INS) | VAF 66/452 reads (15%) | called by pindel, varscan2
- GRIK1 | c.2831_2832del p.R944Kfs*29 (on ENST00000327783 / NM_001330994.2; = p.R900Kfs*29 on NM_175611.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 74/229 reads (32%) | called by pindel, varscan2
- H2BC6 | c.368C>T p.T123I | Missense Mutation (SNP) | VAF 106/222 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- IFRD1 | c.1186C>T p.R396* | Nonsense Mutation (SNP) | VAF 158/330 reads (48%) | called by muse, mutect2, varscan2
- IFT88 | c.903T>G p.I301M (on ENST00000319980 / NM_001318493.2; = p.I292M on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 220/398 reads (55%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- IGSF10 | c.6134A>G p.Y2045C | Missense Mutation (SNP) | VAF 215/434 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- INO80D | c.1547A>G p.N516S | Missense Mutation (SNP) | VAF 112/228 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- IZUMO3 | c.140G>T p.R47L | Missense Mutation (SNP) | VAF 186/466 reads (40%) | SIFT deleterious (0.04); called by muse, mutect2
- KCNN2 | c.656T>C p.L219S (on ENST00000264773; = p.L431S on NM_021614.4) | Missense Mutation (SNP) | VAF 191/405 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- KIF27 | c.1215A>C p.Q405H | Missense Mutation (SNP) | VAF 40/450 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- KIF2A | c.2000T>A p.L667H | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KRT4 | c.929A>C p.E310A | Missense Mutation (SNP) | VAF 28/380 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- LCT | c.3329A>C p.E1110A | Missense Mutation (SNP) | VAF 37/558 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.643); called by muse, mutect2
- LMAN1L | c.1294C>A p.L432I | Missense Mutation (SNP) | VAF 181/361 reads (50%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- LRRC2 | c.134A>T p.E45V | Missense Mutation (SNP) | VAF 92/240 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- MACF1 | c.11705A>T p.E3902V (on ENST00000372915; = p.E1835V on NM_012090.5) | Missense Mutation (SNP) | VAF 36/347 reads (10%) | called by muse, mutect2, varscan2
- MAN2C1 | c.506A>C p.K169T | Missense Mutation (SNP) | VAF 29/578 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); called by muse, mutect2
- MAP3K6 | c.1277T>A p.L426Q | Missense Mutation (SNP) | VAF 202/419 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP7D2 | c.1929A>C p.E643D | Missense Mutation (SNP) | VAF 28/478 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.096); called by muse, mutect2
- MATK | c.89T>A p.L30H (on ENST00000310132 / NM_139355.3; = p.L31H on NM_002378.4) | Missense Mutation (SNP) | VAF 192/406 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.322); called by mutect2, varscan2
- MOB1A | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 171/351 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MOV10L1 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 159/348 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MPDZ | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 79/166 reads (48%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTRF1L | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 200/360 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- MYOC | c.491A>G p.E164G | Missense Mutation (SNP) | VAF 40/1083 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.055); called by muse, mutect2
- NEDD4L | c.2513A>G p.D838G (on ENST00000400345 / NM_001144967.3; = p.D818G on NM_015277.6) | Missense Mutation (SNP) | VAF 48/49 reads (98%) | SIFT deleterious (0.05); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- NHS | c.73G>T p.V25L | Missense Mutation (SNP) | VAF 305/626 reads (49%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP5 | c.3143A>G p.H1048R | Missense Mutation (SNP) | VAF 119/551 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NOTCH3 | c.5695T>A p.L1899M | Missense Mutation (SNP) | VAF 20/520 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NUP210L | c.2036C>T p.P679L | Missense Mutation (SNP) | VAF 546/791 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR10J4 | c.797A>G p.K266R | Missense Mutation (SNP) | VAF 520/687 reads (76%) | called by muse, mutect2, varscan2
- OR1L6 | c.583T>C p.F195L (on ENST00000373684; = p.F159L on NM_001004453.2) | Missense Mutation (SNP) | VAF 32/493 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- OR8H3 | c.462G>C p.M154I | Missense Mutation (SNP) | VAF 127/328 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PACS1 | c.2735G>A p.R912H | Missense Mutation (SNP) | VAF 178/378 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PAGE3 | c.190C>T p.Q64* | Nonsense Mutation (SNP) | VAF 97/218 reads (44%) | called by muse, mutect2, varscan2
- PCDHA2 | c.1066T>C p.S356P | Missense Mutation (SNP) | VAF 26/358 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- PCDHA4 | c.53T>G p.L18R | Missense Mutation (SNP) | VAF 49/568 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.853); called by muse, mutect2
- PCDHA4 | c.362T>G p.V121G | Missense Mutation (SNP) | VAF 50/540 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHB13 | c.1865G>A p.G622D | Missense Mutation (SNP) | VAF 378/821 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PEG3 | c.824C>A p.S275* | Nonsense Mutation (SNP) | VAF 184/772 reads (24%) | called by muse, mutect2, varscan2
- PER3 | c.184A>C p.M62L | Missense Mutation (SNP) | VAF 193/426 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- PHOSPHO2 | c.187C>T p.H63Y | Missense Mutation (SNP) | VAF 14/365 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2
- PIEZO2 | c.361A>G p.R121G | Missense Mutation (SNP) | VAF 138/322 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- PKHD1 | c.6048T>G p.S2016R | Missense Mutation (SNP) | VAF 45/542 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLCD3 | c.1823A>G p.Q608R | Missense Mutation (SNP) | VAF 166/324 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- POU5F1B | c.685G>C p.A229P | Missense Mutation (SNP) | VAF 889/1877 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PRPF8 | c.4751A>C p.K1584T | Missense Mutation (SNP) | VAF 48/528 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- PRR23D2 | c.150del p.K50Nfs*10 | Frame Shift Del (DEL) | VAF 30/198 reads (15%) | called by mutect2, varscan2
- PRTG | c.3057G>T p.M1019I | Missense Mutation (SNP) | VAF 132/295 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM4 | c.511T>C p.W171R | Missense Mutation (SNP) | VAF 42/504 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- RGS18 | c.89A>G p.K30R | Missense Mutation (SNP) | VAF 165/239 reads (69%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RMI1 | c.286A>T p.S96C | Missense Mutation (SNP) | VAF 40/362 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RYR2 | c.4843C>A p.Q1615K | Missense Mutation (SNP) | VAF 589/773 reads (76%) | SIFT tolerated (0.39); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SHOC2 | c.972G>T p.E324D | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT tolerated (0.84); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SIPA1L2 | c.2693G>A p.R898K | Missense Mutation (SNP) | VAF 209/871 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SLC22A2 | c.642C>G p.S214R | Missense Mutation (SNP) | VAF 24/387 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2
- SLCO5A1 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 36/538 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLF2 | c.2470G>A p.V824M | Missense Mutation (SNP) | VAF 97/240 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SMARCC2 | c.2083T>G p.S695A | Missense Mutation (SNP) | VAF 33/295 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SOX9 | c.1334A>C p.H445P | Missense Mutation (SNP) | VAF 285/285 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- SPTBN4 | c.2437C>T p.R813C | Missense Mutation (SNP) | VAF 382/1449 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- SRGAP3 | c.970C>A p.Q324K | Missense Mutation (SNP) | VAF 204/478 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- SRSF12 | c.548A>T p.K183M | Missense Mutation (SNP) | VAF 170/362 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- ST6GAL2 | c.1517A>G p.K506R | Missense Mutation (SNP) | VAF 38/482 reads (8%) | PolyPhen benign (0.261); called by muse, mutect2
- STEAP1 | c.502A>G p.S168G | Missense Mutation (SNP) | VAF 216/396 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- STON1 | c.2185del p.I729Lfs*5 | Frame Shift Del (DEL) | VAF 116/317 reads (37%) | called by mutect2, pindel, varscan2
- SUN5 | c.254A>G p.Q85R | Missense Mutation (SNP) | VAF 38/462 reads (8%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.058); called by muse, mutect2
- TAFA3 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 145/315 reads (46%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEX15 | c.4159G>A p.E1387K (on ENST00000256246; = p.E1770K on NM_001350162.2) | Missense Mutation (SNP) | VAF 13/497 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.046); called by muse, mutect2
- THBD | c.1340A>C p.N447T | Missense Mutation (SNP) | VAF 32/568 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- TMEM240 | c.309C>G p.F103L | Missense Mutation (SNP) | VAF 368/760 reads (48%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM47 | c.1652G>T p.C551F | Missense Mutation (SNP) | VAF 304/614 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TRPM1 | c.556A>C p.T186P | Missense Mutation (SNP) | VAF 30/370 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.239); called by muse, mutect2
- TTC30B | c.1315A>C p.N439H | Missense Mutation (SNP) | VAF 229/586 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- TXLNA | c.932A>C p.K311T | Missense Mutation (SNP) | VAF 21/288 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.933); called by muse, mutect2
- URI1 | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 90/365 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- USP28 | c.2224G>A p.V742I | Missense Mutation (SNP) | VAF 165/373 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2
- WDR87 | c.6694A>C p.S2232R | Missense Mutation (SNP) | VAF 48/978 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); called by muse, mutect2
- WNT10A | c.335C>T p.T112I | Missense Mutation (SNP) | VAF 203/426 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- ZFAND4 | c.1978A>G p.K660E | Missense Mutation (SNP) | VAF 115/221 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- ZFYVE16 | c.3734T>G p.L1245R | Missense Mutation (SNP) | VAF 93/186 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- ZNF429 | c.1325G>C p.R442T | Missense Mutation (SNP) | VAF 122/263 reads (46%) | SIFT tolerated (0.77); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF469 | c.9071A>C p.K3024T (on ENST00000437464; = p.K3052T on NM_001367624.2) | Missense Mutation (SNP) | VAF 24/653 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.142); called by muse, mutect2
- ZNF470 | c.285C>A p.D95E | Missense Mutation (SNP) | VAF 49/269 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- ZNF585A | c.2192C>A p.S731Y (on ENST00000292841 / NM_001288800.2; = p.S676Y on NM_152655.3) | Missense Mutation (SNP) | VAF 195/901 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF831 | c.2358A>C p.E786D | Missense Mutation (SNP) | VAF 49/494 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.537); called by muse, mutect2
- ZNF836 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 134/548 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ZXDC | c.2537A>T p.Q846L | Missense Mutation (SNP) | VAF 25/550 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2
- ABCA13 | c.1530C>T p.F510= | Silent (SNP) | VAF 185/372 reads (50%) | catalogued as COSV70046534; called by muse, mutect2, varscan2
- ADAMTS12 | c.1810C>A p.R604= | Silent (SNP) | VAF 135/268 reads (50%) | catalogued as COSV61261873; called by mutect2, varscan2
- AKAP9 | c.6381G>A p.K2127= (on ENST00000359028; = p.K2095= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 171/304 reads (56%) | called by muse, mutect2, varscan2
- AMER2 | c.402G>T p.G134= | Silent (SNP) | VAF 319/474 reads (67%) | catalogued as rs1019197116; called by muse, mutect2, varscan2
- ANKMY1 | c.897G>A p.A299= | Silent (SNP) | VAF 150/291 reads (52%) | catalogued as rs768098181; called by muse, mutect2, varscan2
- AP3B2 | c.1455C>A p.I485= | Silent (SNP) | VAF 166/347 reads (48%) | called by muse, mutect2, varscan2
- ARHGAP29 | c.1198A>C p.R400= | Silent (SNP) | VAF 28/373 reads (8%) | called by muse, mutect2
- BMPR2 | c.939T>C p.A313= | Silent (SNP) | VAF 38/422 reads (9%) | called by muse, mutect2
- BRCA1 | c.2097G>A p.E699= | Silent (SNP) | VAF 187/362 reads (52%) | called by muse, mutect2, varscan2
- BRINP3 | c.1251C>A p.G417= | Silent (SNP) | VAF 156/713 reads (22%) | called by muse, mutect2, varscan2
- CACNA1C | c.5181G>A p.P1727= | Silent (SNP) | VAF 277/590 reads (47%) | catalogued as rs370149297; ClinVar: likely benign; called by muse, mutect2, varscan2
- CC2D2A | c.3282C>T p.L1094= | Silent (SNP) | VAF 160/344 reads (47%) | catalogued as rs766917693, COSV67504650; called by muse, mutect2, varscan2
- CHADL | c.340C>T p.L114= | Silent (SNP) | VAF 333/681 reads (49%) | called by muse, mutect2, varscan2
- CHD3 | c.741T>C p.A247= | Silent (SNP) | VAF 20/198 reads (10%) | called by muse, mutect2
- CNTNAP2 | c.1785C>T p.Y595= | Silent (SNP) | VAF 96/216 reads (44%) | catalogued as rs781574808, COSV62155069; called by muse, mutect2, varscan2
- CR1L | c.150T>G p.T50= | Silent (SNP) | VAF 46/1092 reads (4%) | called by muse, mutect2
- DISP1 | c.2454C>T p.I818= | Silent (SNP) | VAF 48/973 reads (5%) | catalogued as rs764747224, COSV52654995, COSV52664226; called by muse, mutect2
- ELOA | c.2004A>T p.R668= | Silent (SNP) | VAF 15/323 reads (5%) | called by muse, mutect2
- ERBB2 | c.2670G>A p.A890= | Silent (SNP) | VAF 164/391 reads (42%) | catalogued as rs140453509; called by muse, mutect2, varscan2
- FARP1 | c.2445C>T p.S815= | Silent (SNP) | VAF 254/523 reads (49%) | catalogued as rs779847995; called by muse, mutect2, varscan2
- FOXG1 | c.783C>T p.S261= | Silent (SNP) | VAF 276/544 reads (51%) | catalogued as rs796934848; called by muse, mutect2, varscan2
- GAL3ST1 | c.1053C>T p.A351= | Silent (SNP) | VAF 362/715 reads (51%) | catalogued as rs1351086553, COSV100143187; called by muse, mutect2, varscan2
- GUCY2D | c.849C>T p.Y283= | Silent (SNP) | VAF 251/546 reads (46%) | catalogued as rs143745703, CM078219, CM155705; called by muse, mutect2, varscan2
- HERC5 | c.663A>G p.G221= | Silent (SNP) | VAF 121/252 reads (48%) | called by muse, mutect2, varscan2
- HMCN1 | c.8001C>T p.P2667= | Silent (SNP) | VAF 336/454 reads (74%) | called by muse, mutect2, varscan2
- HOXC12 | c.447C>T p.D149= | Silent (SNP) | VAF 247/516 reads (48%) | called by muse, mutect2, varscan2
- HPS3 | c.135G>A p.A45= | Silent (SNP) | VAF 305/667 reads (46%) | catalogued as rs754575715; called by muse, mutect2, varscan2
- HRNR | c.3132C>T p.S1044= | Silent (SNP) | VAF 976/1533 reads (64%) | catalogued as rs780924307, COSV64261081; called by muse, mutect2, varscan2
- IGHG1 | c.849C>T p.S283= | Silent (SNP) | VAF 78/887 reads (9%) | catalogued as rs752858009; called by muse, mutect2
- IGLON5 | c.612G>A p.A204= | Silent (SNP) | VAF 194/863 reads (22%) | catalogued as COSV99570633; called by muse, mutect2, varscan2
- IL27RA | c.255C>T p.A85= | Silent (SNP) | VAF 255/499 reads (51%) | catalogued as rs370388608; called by muse, mutect2, varscan2
- IRS4 | c.543C>T p.A181= | Silent (SNP) | VAF 258/512 reads (50%) | called by muse, mutect2, varscan2
- JARID2 | c.1425G>A p.P475= | Silent (SNP) | VAF 282/594 reads (47%) | catalogued as rs746665947, COSV100522039; called by muse, mutect2, varscan2
- KAZN | c.789G>A p.P263= | Silent (SNP) | VAF 233/509 reads (46%) | catalogued as rs754892530; called by muse, mutect2, varscan2
- KEL | c.1488C>T p.N496= | Silent (SNP) | VAF 180/406 reads (44%) | catalogued as rs139823086; called by muse, varscan2
- KIF4A | c.2871G>A p.Q957= | Silent (SNP) | VAF 150/315 reads (48%) | called by muse, mutect2, varscan2
- LILRB2 | c.933C>T p.D311= | Silent (SNP) | VAF 157/815 reads (19%) | catalogued as rs1438868065; called by muse, mutect2
- LRP2 | c.2220T>G p.P740= | Silent (SNP) | VAF 33/529 reads (6%) | catalogued as rs1172954254; called by muse, mutect2
- LYST | c.5589G>A p.Q1863= | Silent (SNP) | VAF 360/492 reads (73%) | called by muse, mutect2, varscan2
- MSH4 | c.303T>G p.T101= | Silent (SNP) | VAF 34/444 reads (8%) | called by muse, mutect2
- MYF5 | c.117C>T p.F39= | Silent (SNP) | VAF 44/583 reads (8%) | catalogued as COSV57354278; called by muse, mutect2
- MYO7A | c.2322C>T p.I774= | Silent (SNP) | VAF 175/415 reads (42%) | called by muse, mutect2, varscan2
- MYO7B | c.2130C>T p.N710= | Silent (SNP) | VAF 173/371 reads (47%) | catalogued as rs756866229, COSV101268330; called by muse, mutect2, varscan2
- NEB | c.11658G>T p.G3886= | Silent (SNP) | VAF 156/306 reads (51%) | called by mutect2, varscan2
- NKX2-6 | c.252C>T p.D84= | Silent (SNP) | VAF 114/403 reads (28%) | catalogued as COSV61492684; called by muse, mutect2, varscan2
- NT5C1B | c.945C>T p.C315= (on ENST00000359846 / NM_001199086.2; = p.C255= on NM_033253.4) | Silent (SNP) | VAF 166/351 reads (47%) | catalogued as rs559538037, COSV58397402; called by muse, mutect2, varscan2
- OR4L1 | c.744T>C p.T248= | Silent (SNP) | VAF 40/474 reads (8%) | called by muse, mutect2
- PCDHA1 | c.1611G>A p.A537= | Silent (SNP) | VAF 350/753 reads (46%) | catalogued as COSV65372654; called by muse, mutect2, varscan2
- PCDHA12 | c.1389C>T p.F463= | Silent (SNP) | VAF 362/732 reads (49%) | catalogued as COSV56477300; called by muse, mutect2, varscan2
- PCDHGA11 | c.1644G>A p.S548= | Silent (SNP) | VAF 238/503 reads (47%) | catalogued as rs769543752, COSV53947486, COSV53984994; called by muse, mutect2, varscan2
- PLCD4 | c.1486C>T p.L496= | Silent (SNP) | VAF 204/415 reads (49%) | called by muse, mutect2, varscan2
- PPP1R2B | c.255G>A p.A85= | Silent (SNP) | VAF 154/289 reads (53%) | catalogued as COSV70372784; called by muse, mutect2, varscan2
- PRSS36 | c.879A>G p.S293= | Silent (SNP) | VAF 299/614 reads (49%) | called by muse, mutect2, varscan2
- RPS4X | c.201G>A p.Q67= | Silent (SNP) | VAF 269/609 reads (44%) | catalogued as rs11545416; called by muse, mutect2, varscan2
- SIN3A | c.1566G>A p.L522= | Silent (SNP) | VAF 175/377 reads (46%) | called by muse, mutect2, varscan2
- SLC16A8 | c.550C>T p.L184= | Silent (SNP) | VAF 297/637 reads (47%) | called by muse, mutect2, varscan2
- SLC25A6 | c.726C>T p.S242= | Silent (SNP) | VAF 246/491 reads (50%) | catalogued as rs369739787, COSV58431726; called by muse, mutect2, varscan2
- SLC28A1 | c.1275C>T p.V425= | Silent (SNP) | VAF 268/520 reads (52%) | catalogued as rs1270603538, COSV99723611; called by muse, mutect2, varscan2
- SOWAHD | c.642T>C p.A214= | Silent (SNP) | VAF 64/843 reads (8%) | called by muse, mutect2
- SRPX2 | c.255G>A p.T85= | Silent (SNP) | VAF 302/622 reads (49%) | called by muse, mutect2, varscan2
- SYNE1 | c.24276G>A p.L8092= (on ENST00000367255 / NM_182961.4; = p.L8021= on NM_033071.3) | Silent (SNP) | VAF 166/343 reads (48%) | catalogued as rs1448329995; called by muse, mutect2, varscan2
- SYT7 | c.399A>G p.R133= | Silent (SNP) | VAF 67/538 reads (12%) | called by muse, mutect2, varscan2
- TCEANC | c.727T>C p.L243= (on ENST00000380600 / NM_001297563.2; = p.L273= on NM_152634.4) | Silent (SNP) | VAF 34/523 reads (7%) | called by muse, mutect2
- TDG | c.831T>A p.A277= | Silent (SNP) | VAF 14/270 reads (5%) | called by muse, mutect2
- TESPA1 | c.1236G>A p.E412= (on ENST00000316577 / NM_001098815.3; = p.E274= on NM_014796.2 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 157/349 reads (45%) | called by muse, mutect2, varscan2
- TMEM123 | c.402C>T p.T134= | Silent (SNP) | VAF 169/345 reads (49%) | catalogued as rs927008036; called by muse, mutect2, varscan2
- TMEM161B | c.1008T>G p.A336= | Silent (SNP) | VAF 164/363 reads (45%) | called by muse, mutect2, varscan2
- TNFSF9 | c.462C>T p.A154= | Silent (SNP) | VAF 312/688 reads (45%) | catalogued as rs780728549; called by muse, mutect2, varscan2
- TRIP4 | c.1515T>G p.G505= | Silent (SNP) | VAF 34/449 reads (8%) | called by muse, mutect2
- TUBB4A | c.312G>A p.G104= | Silent (SNP) | VAF 160/324 reads (49%) | catalogued as COSV99900003; called by muse, mutect2, varscan2
- USP42 | c.3276G>A p.P1092= | Silent (SNP) | VAF 312/618 reads (50%) | catalogued as rs1481056650, COSV60357410; called by muse, mutect2, varscan2
- VPS72 | c.618G>A p.K206= | Silent (SNP) | VAF 568/787 reads (72%) | called by muse, mutect2, varscan2
- XKR4 | c.45C>T p.S15= | Silent (SNP) | VAF 182/528 reads (34%) | catalogued as rs1403261466, COSV59331262; called by muse, varscan2
- ZC3H7B | c.1782C>T p.I594= | Silent (SNP) | VAF 174/387 reads (45%) | catalogued as rs750421965, COSV60960853; called by muse, mutect2, varscan2
- ZNF14 | c.1806T>A p.V602= | Silent (SNP) | VAF 242/492 reads (49%) | called by muse, mutect2, varscan2
- ZNF185 | c.807C>T p.P269= | Silent (SNP) | VAF 169/412 reads (41%) | called by muse, mutect2, varscan2
- ZNF423 | c.864G>A p.K288= (on ENST00000563137 / NM_001379286.1; = p.K280= on NM_015069.4) | Silent (SNP) | VAF 205/438 reads (47%) | catalogued as rs201849640; called by muse, mutect2, varscan2
- ZNF732 | c.924T>C p.C308= | Silent (SNP) | VAF 36/330 reads (11%) | catalogued as rs782332681; called by muse, mutect2, varscan2
- ZNF836 | c.774C>A p.G258= | Silent (SNP) | VAF 192/842 reads (23%) | called by muse, mutect2, varscan2
- ATP11C | c.*9G>A | 3'UTR (SNP) | VAF 122/256 reads (48%) | catalogued as rs769803618; called by muse, mutect2, varscan2
- COL11A1 | c.2142+308C>T | Intron (SNP) | VAF 55/149 reads (37%) | called by muse, mutect2, varscan2
- COQ4 | c.202+165T>C | Intron (SNP) | VAF 237/511 reads (46%) | called by muse, mutect2, varscan2
- MLLT10 | c.240+18008G>A | Intron (SNP) | VAF 99/238 reads (42%) | catalogued as rs764402984; called by muse, mutect2, varscan2
- PAX3 | chr2:222201213 G>A | 3'Flank (SNP) | VAF 180/392 reads (46%) | catalogued as rs776608873, COSV60589495; called by muse, mutect2, varscan2
- PIK3R2 | c.-167G>T | 5'UTR (SNP) | VAF 221/473 reads (47%) | called by muse, mutect2, varscan2
- PRR29 | c.*985G>T | 3'UTR (SNP) | VAF 147/278 reads (53%) | catalogued as COSV56744259; called by muse, mutect2, varscan2
- TENT5A | c.-188C>T | 5'UTR (SNP) | VAF 171/361 reads (47%) | called by muse, mutect2, varscan2
- ZNF33A | c.10-882C>T | Intron (SNP) | VAF 110/276 reads (40%) | called by muse, mutect2, varscan2
